CCDI case PBBUYK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c0ee4244-3caf-489b-96c9-efe78dab7b17

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 12.2 years (4,452 days).

Biospecimens (3 samples)
- Sample 0DHQDJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHQE8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHQFF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
